Surgical pathology report (de-identified scan), TCGA case TCGA-B8-4148, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-4148-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Surgical Pathology Report

Accession #:

Diagnosis:

Kidney, left, partial nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Histologic grade (if applicable): 3 (of 4)

Tumor size (greatest dimension): 2.6 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: free of tumor

Parenchymal renal margin: free of tumor

AJCC Staging:

pT1a

pNx

pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

with a renal mass.

[page 2 of 2]
Gross Description:

Received is one appropriately labeled container, additionally labeled "left kidney tumor" and is a 10.4 gram, 4 x 3 x 2.7 cm partial nephrectomy specimen is received with a minimal amount of attached perinephric fat. The capsule is smooth, tan and marked with green ink. The parenchymal margin is inked with purple ink. The specimen is sectioned to reveal a solitary well-circumscribed 2.6 x 2.2 x 2.2 cm lobulated tan mass, focally abutting the green inked capsular margin and the purple inked parenchymal margin. There is a rim of compressed renal tissue at the periphery. Representative sections are submitted in blocks A1-A4.

Source: NCI Genomic Data Commons file 54f4d8c7-f21f-4e35-b233-4a8428e1af1b (TCGA-B8-4148.1F31143E-6E26-4ED8-8D1F-20655565ED43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).